Somatic mutation profile of tumor specimen ALCH-B0H7-TTP1-A (aliquot ALCH-B0H7-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B0H7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 59.6 years (21,759 days).
Specimen ALCH-B0H7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 481ebeee-f6d6-4908-8cbd-df0643114013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0H7-NB1-A (Blood Derived Normal), aliquot ALCH-B0H7-NB1-A-2-1-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a59441f-6d03-43ab-ae2f-8f93fd8a2fb0

The open-access MAF lists 654 somatic variants for this specimen: 436 protein-altering or splice-affecting, 130 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 378, Silent 130, Intron 41, Nonsense Mutation 23, RNA 19, Splice Site 12, Frame Shift Del 10, 3'UTR 9, 5'Flank 8, Frame Shift Ins 6, 5'UTR 6, 3'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 258/657 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs1562983147, COSV99709891; ClinVar: uncertain significance; called by muse, mutect2
- ACY3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54829794; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 152/445 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781547594, COSV58446584; called by muse, mutect2, varscan2
- ADGRG4 | c.5996C>G p.S1999C | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV99796741; called by muse, mutect2, varscan2
- AFDN | c.3560G>A p.S1187N | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1362222938; called by muse, mutect2
- AQP12B | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as COSV68183970; called by muse, mutect2
- ARHGAP18 | c.1093C>G p.R365G | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543407407, COSV63766179; called by muse, mutect2, varscan2
- ARHGAP21 | c.4756G>T p.D1586Y | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57608174; called by muse, mutect2, varscan2
- ATP7B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1425712013; called by muse, mutect2, varscan2
- B4GALNT4 | c.2003C>A p.A668E | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV57323112; called by muse, mutect2
- BAZ1A | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs776604953; called by muse, mutect2
- BCL11B | c.1241C>A p.P414H (on ENST00000357195 / NM_001282237.2; = p.P343H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV61736384, COSV61736639; called by muse, mutect2, varscan2
- C6orf118 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs140022567, COSV57817681; called by muse, mutect2, varscan2
- CACNA1G | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61736156; called by muse, mutect2
- CACNA1G | c.2778C>A p.N926K | Missense Mutation (SNP) | VAF 119/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61733646; called by muse, mutect2, varscan2
- CBLN1 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 148/332 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54653889; called by muse, mutect2, varscan2
- CD163L1 | c.3483C>A p.N1161K | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58010602; called by muse, mutect2, varscan2
- CD40 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 191/753 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs987910986; called by muse, mutect2, varscan2
- CDH4 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 367/1126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1170788458, COSV64663928; called by muse, mutect2, varscan2
- CELSR1 | c.4291C>T p.P1431S | Missense Mutation (SNP) | VAF 113/564 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs200569320; called by muse, varscan2
- CEP295NL | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 127/533 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs542640508; called by muse, mutect2, varscan2
- CNTNAP4 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1376353889; called by muse, mutect2
- COQ2 | c.170del p.A57Gfs*115 | Frame Shift Del (DEL) | VAF 71/540 reads (13%) | catalogued as COSV100269910; called by mutect2, pindel, varscan2
- CSMD1 | c.3023C>A p.T1008K (on ENST00000520002; = p.T1007K on NM_033225.6) | Missense Mutation (SNP) | VAF 91/654 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs147113316, COSV59282026; called by muse, mutect2, varscan2
- CSMD1 | c.2051G>T p.R684I (on ENST00000520002; = p.R683I on NM_033225.6) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs778893537, COSV100149013; called by mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2
- CYBB | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as CM106219; called by muse, mutect2, varscan2
- DCAF8L1 | c.490C>G p.R164G | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV71595352; called by muse, mutect2, varscan2
- DDX11 | c.1864A>T p.T622S | Missense Mutation (SNP) | VAF 142/870 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52505146; called by muse, mutect2, varscan2
- DNASE1L3 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs563166164; called by muse, mutect2, varscan2
- DRD5 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV58577570; called by muse, mutect2, varscan2
- EPHA1 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 245/704 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51973967; called by muse, mutect2, varscan2
- EPHB4 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs760826885; called by muse, mutect2, varscan2
- EPYC | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53802284; called by muse, mutect2, varscan2
- ERCC6L | c.159T>A p.N53K | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs368590575; called by muse, mutect2, varscan2
- EXOSC10 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776918924, COSV58665201; called by muse, mutect2
- F8 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CD011151, CM005336, CM1414429, CM1510587; called by muse, mutect2
- FADS1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1239360783; called by muse, mutect2, varscan2
- FAM155B | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 59/664 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52935847; called by muse, mutect2
- FAM170A | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.855); catalogued as COSV100088899; called by muse, mutect2, varscan2
- FAN1 | c.1705G>T p.G569* | Nonsense Mutation (SNP) | VAF 71/415 reads (17%) | catalogued as COSV62952267; called by muse, mutect2, varscan2
- FCGBP | c.4310G>T p.G1437V | Missense Mutation (SNP) | VAF 28/760 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55433989; called by muse, mutect2
- FLRT1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 119/407 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs768000465, COSV55356315; called by muse, mutect2, varscan2
- FLRT2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs769115922; called by muse, mutect2, varscan2
- FOXF1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99296392; called by muse, mutect2, varscan2
- FOXI1 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV60387990; called by muse, mutect2, varscan2
- FSHR | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 96/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100436806; called by muse, mutect2, varscan2
- FZR1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV58052155; called by muse, mutect2, varscan2
- GPLD1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs565249214, COSV57757683; called by muse, mutect2
- GPR101 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.908); catalogued as COSV53239305, COSV99035716; called by muse, varscan2
- GRM6 | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 213/587 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51445322; called by muse, mutect2, varscan2
- HEPHL1 | c.3155C>G p.S1052C | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1218002310; called by muse, mutect2
- HLCS | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 137/501 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960836, COSV60795798; called by muse, mutect2, varscan2
- HTR2C | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV52213889; called by muse, mutect2
- IGHV1-46 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 112/537 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs192285778; called by muse, mutect2, varscan2
- ITPR1 | c.1647C>G p.F549L (on ENST00000354582; = p.F534L on NM_002222.7) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV56994520; called by muse, mutect2, varscan2
- KAT6A | c.4049C>G p.S1350C | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as COSV99705919; called by muse, mutect2, varscan2
- KIAA1549 | c.3457G>T p.E1153* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99652310; called by mutect2, varscan2
- KLHL14 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs747083891; called by muse, mutect2, varscan2
- KRI1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV57265522; called by muse, mutect2, varscan2
- KRT80 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 31/566 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs565212849, COSV57548306; called by muse, mutect2
- KRT9 | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 72/581 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55852445; called by muse, mutect2, varscan2
- LAMB2 | c.4429G>T p.V1477L | Missense Mutation (SNP) | VAF 124/523 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV59731630; called by muse, mutect2, varscan2
- LCOR | c.2953C>G p.Q985E | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.287); catalogued as rs1476535348; called by muse, mutect2, varscan2
- LMOD2 | c.1537C>G p.R513G | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101505451; called by muse, mutect2, varscan2
- LPAR4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755428031; called by muse, mutect2, varscan2
- LRP3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458955578; called by muse, mutect2
- LRRC49 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs199883910, COSV53011514; called by muse, mutect2, varscan2
- MCM6 | c.2305A>G p.K769E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as rs1423071891, COSV51465164; called by muse, mutect2, varscan2
- MDC1 | c.2908G>T p.G970W | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV64527687; called by muse, mutect2, varscan2
- MEGF8 | c.2987G>T p.S996I (on ENST00000251268 / NM_001271938.2; = p.S929I on NM_001410.3) | Missense Mutation (SNP) | VAF 163/481 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1223817524; called by muse, mutect2, varscan2
- MMP12 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs550934359, COSV100405132; called by muse, varscan2
- MMRN1 | c.1766G>T p.R589I | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as rs764406742; called by muse, mutect2, varscan2
- MSL2 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 49/494 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53860307; called by muse, mutect2
- MXRA5 | c.6422G>T p.R2141L | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV54248850; called by muse, mutect2, varscan2
- MYCN | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 94/885 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99808365; called by muse, mutect2, varscan2
- MYH9 | c.2499G>T p.K833N | Missense Mutation (SNP) | VAF 200/735 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99338829; called by muse, mutect2, varscan2
- NDP | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 153/622 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65203966; called by muse, mutect2, varscan2
- NMRK2 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104383395, COSV51455152; called by muse, mutect2, varscan2
- NOS2 | c.2513C>A p.P838Q | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100569548; called by muse, varscan2
- OGDH | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56048218; called by muse, mutect2
- OR2M7 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs768101785; called by muse, mutect2, varscan2
- OR4C13 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.141); catalogued as COSV101634244; called by muse, mutect2, varscan2
- OR4S2 | c.667del p.L223* | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as COSV56746397; called by mutect2, pindel, varscan2
- OR52E4 | c.298del p.L100Ffs*37 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | catalogued as COSV57626218; called by mutect2, pindel, varscan2
- OR52K2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57834893; called by muse, mutect2, varscan2
- OR5D14 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs150222887; called by muse, mutect2, varscan2
- PCDH8 | c.2835G>T p.Q945H | Missense Mutation (SNP) | VAF 175/396 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV58814859; called by muse, mutect2, varscan2
- PCNX1 | c.1739A>G p.Y580C | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as rs371433454; called by muse, mutect2, varscan2
- PDHA2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 117/567 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.531); catalogued as rs1281704703, COSV54779764; called by muse, mutect2, varscan2
- PIDD1 | c.2416G>T p.V806L | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as COSV57194556; called by muse, mutect2, varscan2
- PLCH2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 181/691 reads (26%) | catalogued as rs942316550, COSV53944983; called by muse, mutect2, varscan2
- POLR2B | c.2924G>T p.R975L | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58899541; called by muse, mutect2, varscan2
- POM121 | c.2923G>C p.A975P (on ENST00000434423; = p.A710P on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.785); catalogued as COSV99987312; called by muse, mutect2, varscan2
- POM121L12 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs746047304, COSV68692144; called by muse, mutect2, varscan2
- POM121L12 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 126/353 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV68692920, COSV68692994; called by muse, mutect2, varscan2
- POT1 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62933692; called by muse, mutect2, varscan2
- PPP4R3C | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69081044; called by muse, mutect2, varscan2
- PRPS1L1 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 147/405 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.892); catalogued as COSV101552929; called by muse, mutect2, varscan2
- PRRX1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 142/617 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV99509088; called by muse, mutect2, varscan2
- PTGER2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 89/530 reads (17%) | catalogued as COSV55418384; called by muse, mutect2, varscan2
- PXDN | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1440817288; called by muse, mutect2
- RAB11FIP1 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV54758290; called by muse, mutect2
- RADIL | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 85/627 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV68200429; called by muse, mutect2, varscan2
- RAG2 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 70/636 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558650; called by muse, mutect2, varscan2
- RBMXL2 | c.210C>G p.N70K | Missense Mutation (SNP) | VAF 155/1045 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60978939; called by muse, mutect2, varscan2
- RBMXL3 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs782408670, COSV57747838; called by muse, mutect2, varscan2
- RPE65 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV52015879; called by muse, mutect2
- SATB2 | c.526C>G p.R176G | Missense Mutation (SNP) | VAF 109/491 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99611583; called by muse, mutect2, varscan2
- SCN10A | c.1775del p.K592Rfs*10 | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | catalogued as COSV71861341; called by mutect2, pindel, varscan2
- SHISA2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 243/523 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs760898953, COSV60112121; called by muse, mutect2, varscan2
- SPANXN1 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV65123274; called by muse, mutect2
- STAB1 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs757142553, COSV58733082, COSV58742914; called by muse, mutect2
- STC1 | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51689555; called by muse, mutect2, varscan2
- STK10 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs369577776; called by muse, mutect2, varscan2
- STK16 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 166/656 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1224400397; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59125662; called by muse, mutect2, varscan2
- STYXL2 | c.535T>A p.Y179N | Missense Mutation (SNP) | VAF 153/751 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610078; called by muse, mutect2, varscan2
- TBC1D8 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV65211211; called by muse, mutect2
- TCEAL2 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100216412; called by muse, mutect2, varscan2
- TFAP2D | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV50411865; called by muse, mutect2, varscan2
- THBD | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as rs749965272; called by muse, mutect2, varscan2
- TRIM58 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV63570217; called by muse, mutect2, varscan2
- TSPYL2 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs782716321; called by muse, mutect2, varscan2
- TTN | c.92650G>A p.D30884N (on ENST00000591111; = p.D23460N on NM_003319.4) | Missense Mutation (SNP) | VAF 67/200 reads (34%) | PolyPhen benign (0.01); catalogued as COSV59934071; called by muse, mutect2, varscan2
- USP43 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53300849; called by muse, mutect2, varscan2
- WASHC2C | c.3460A>G p.I1154V (on ENST00000336378; = p.I1133V on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 338/1212 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1336521606; called by muse, mutect2, varscan2
- WDR13 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV54331862; called by muse, mutect2, varscan2
- YTHDC2 | c.2829A>T p.Q943H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV50739849; called by muse, mutect2
- ZNF335 | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100532982; called by muse, mutect2, varscan2
- ZNF727 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs372824901; called by muse, mutect2, varscan2
- ZSCAN18 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 92/343 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729722; called by muse, mutect2, varscan2
- AADACL2 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- ACSF2 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSF3 | c.374T>A p.L125H | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACVR2A | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 40/673 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2
- ADAM8 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 127/550 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ADAMTS2 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 218/500 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL3 | c.4069C>A p.R1357S (on ENST00000506720 / NM_001322402.2; = p.R1246S on NM_015236.6) | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ADM2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AGT | c.1380C>A p.F460L | Missense Mutation (SNP) | VAF 129/655 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG13 | c.1900G>T p.G634C | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ALPK1 | c.699+1G>T p.X233_splice | Splice Site (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- AQP12A | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 38/784 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.232); called by muse, mutect2
- ARAP3 | c.525-1G>T p.X175_splice | Splice Site (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.3304G>A p.D1102N | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ARHGAP27 | c.1667A>T p.E556V (on ENST00000428638 / NM_001282290.1; = p.E215V on NM_199282.3) | Missense Mutation (SNP) | VAF 143/416 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATCAY | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 179/490 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATF7IP2 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 56/239 reads (23%) | called by muse, mutect2, varscan2
- ATG14 | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | called by muse, varscan2
- ATG16L2 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 135/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATM | c.6026A>G p.Y2009C | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATP2B3 | c.2879C>A p.P960H | Missense Mutation (SNP) | VAF 60/646 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- ATRX | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCO2 | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BLVRA | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- BNC1 | c.1915A>T p.T639S | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- BNC1 | c.1914G>C p.Q638H | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2
- BTD | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- C14orf28 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C1QL1 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 122/1144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- C2orf49 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- C4orf54 | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- C4orf54 | c.3648C>A p.Y1216* | Nonsense Mutation (SNP) | VAF 48/385 reads (12%) | called by muse, mutect2, varscan2
- CACNA1A | c.4818C>G p.I1606M | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CACNA1C | c.4190A>G p.N1397S | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA1F | c.4505G>C p.R1502P | Missense Mutation (SNP) | VAF 58/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.473G>A p.W158* (on ENST00000324631 / NM_201596.3; = p.W103* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 54/263 reads (21%) | called by muse, mutect2, varscan2
- CAMKMT | c.887A>T p.H296L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCT6B | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1C | c.521C>A p.T174K | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD99L2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CD99L2 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CDC42BPB | c.4435T>G p.Y1479D | Missense Mutation (SNP) | VAF 93/519 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CDX4 | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 67/639 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CELSR1 | c.4330A>G p.T1444A | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.241); called by muse, varscan2
- CETN2 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP161 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CFAP299 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- CFAP46 | c.1626G>T p.R542S | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CHSY1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 176/510 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLRN2 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 48/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP3 | c.2948C>T p.T983I | Missense Mutation (SNP) | VAF 234/600 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COCH | c.394T>C p.Y132H (on ENST00000216361 / NM_001347720.1; = p.Y67H on NM_004086.3) | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A2 | c.3980G>C p.G1327A (on ENST00000341947 / NM_080680.3; = p.G1220A on NM_080679.2) | Missense Mutation (SNP) | VAF 104/893 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL6A3 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 117/457 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COP1 | c.1169A>T p.D390V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CPSF6 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CPXM1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPXM2 | c.654G>T p.L218= | Splice Region (SNP) | VAF 50/192 reads (26%) | called by muse, mutect2, varscan2
- CREBBP | c.5306G>T p.R1769L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CSMD1 | c.3998T>A p.L1333H (on ENST00000520002; = p.L1332H on NM_033225.6) | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.3584G>T p.G1195V (on ENST00000297405 / NM_001363185.1; = p.G1091V on NM_052900.3) | Missense Mutation (SNP) | VAF 419/825 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTRB1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 178/701 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- DCAF8L1 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DCC | c.1294C>G p.P432A | Missense Mutation (SNP) | VAF 105/626 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCX | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2
- DGKK | c.3389G>T p.G1130V | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DLG2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLG4 | c.1468A>T p.S490C (on ENST00000399506 / NM_001321075.3; = p.S533C on NM_001365.4) | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMTN | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DNAH17 | c.9957G>T p.R3319S | Missense Mutation (SNP) | VAF 170/608 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC16 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, varscan2
- DPP10 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DPY19L1 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DRP2 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4G3 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ELAVL3 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EP400 | c.7903C>G p.P2635A | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- EPHA7 | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ESPNL | c.1259C>G p.A420G | Missense Mutation (SNP) | VAF 405/716 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FADD | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 231/851 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM170B | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- FAM186A | c.484T>A p.L162I | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- FAM193B | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 65/170 reads (38%) | called by muse, mutect2, varscan2
- FAM47A | c.456C>A p.H152Q | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47B | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 140/807 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- FAM47B | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 141/799 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FAT1 | c.4076A>C p.E1359A | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- FAT3 | c.12426T>A p.N4142K | Missense Mutation (SNP) | VAF 188/584 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FBN1 | c.8470G>A p.A2824T | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FEZF2 | c.1094T>G p.F365C | Missense Mutation (SNP) | VAF 110/434 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FOXD1 | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- FRMPD4 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- FSCN3 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FSIP2 | c.5388dup p.L1797Ifs*10 | Frame Shift Ins (INS) | VAF 33/124 reads (27%) | called by pindel, varscan2
- FZD4 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- G6PD | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRA2 | c.1097C>G p.A366G | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.338); called by muse, mutect2
- GLYAT | c.823del p.M275* | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- GMIP | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- GPR101 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); called by muse, mutect2
- GRB10 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 205/570 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIA3 | c.1479G>T p.M493I | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2
- H3C11 | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 87/604 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HADH | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 87/455 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- HDAC9 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HEPACAM | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 56/416 reads (13%) | called by muse, varscan2
- HFM1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- HLA-B | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 69/525 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- HMCN1 | c.16439A>G p.N5480S | Missense Mutation (SNP) | VAF 106/495 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMGXB4 | c.1007A>T p.E336V | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 149/663 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HS6ST3 | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HUWE1 | c.4336G>A p.G1446S | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HYDIN | c.2196T>A p.Y732* | Nonsense Mutation (SNP) | VAF 49/187 reads (26%) | called by muse, mutect2, varscan2
- IFI27L1 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 82/592 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- IFT52 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- IGKV2D-26 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ILDR1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INSRR | c.2377G>T p.A793S | Missense Mutation (SNP) | VAF 161/603 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- IRF2BP2 | c.639A>T p.L213F | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ITGAD | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ITGAX | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ITGB4 | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 309/1094 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KCNJ1 | c.446_447del p.V149Dfs*66 | Frame Shift Del (DEL) | VAF 104/410 reads (25%) | called by pindel, varscan2
- KCNJ13 | c.-16-8G>C | Splice Region (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- KCNT2 | c.3365G>T p.C1122F | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KIF13A | c.3075+1G>C p.X1025_splice | Splice Site (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- KIF1A | c.4744C>A p.P1582T (on ENST00000320389 / NM_001379639.1; = p.P1574T on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KIF21A | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF26A | c.4051G>T p.G1351C | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- KIRREL1 | c.1172-1G>T p.X391_splice | Splice Site (SNP) | VAF 57/393 reads (15%) | called by muse, mutect2, varscan2
- KMT2D | c.15713G>T p.R5238L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KNDC1 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KRBA1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- KRTAP12-1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KRTAP24-1 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LAMC3 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 276/712 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMP3 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LHFPL4 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2
- LILRB1 | c.1377del p.G461Afs*52 (on ENST00000427581; = p.G425Afs*38 on NM_006669.6) | Frame Shift Del (DEL) | VAF 19/154 reads (12%) | called by mutect2, pindel, varscan2
- LINGO4 | c.368T>C p.M123T | Missense Mutation (SNP) | VAF 107/395 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC25 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 119/492 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAP1A | c.4574A>C p.Q1525P | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MDGA1 | c.1450C>A p.L484M | Missense Mutation (SNP) | VAF 80/598 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MMP2 | c.659-2A>C p.X220_splice | Splice Site (SNP) | VAF 62/545 reads (11%) | called by muse, mutect2, varscan2
- MOGAT3 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MOSMO | c.320-2A>T p.X107_splice | Splice Site (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- MPO | c.1891A>T p.M631L | Missense Mutation (SNP) | VAF 220/940 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MS4A4E | c.171G>T p.M57I (on ENST00000398984; = p.E69* on NM_001351235.2) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MSL3 | c.715A>T p.N239Y (on ENST00000312196 / NM_078629.4; = p.N73Y on NM_006800.4) | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MUC15 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC16 | c.6667A>T p.S2223C | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MUC16 | c.4631G>T p.W1544L | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- MUC2 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MXRA5 | c.413dup p.I139Dfs*58 | Frame Shift Ins (INS) | VAF 34/191 reads (18%) | called by mutect2, pindel, varscan2
- MYH2 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYO7A | c.3092A>T p.D1031V | Missense Mutation (SNP) | VAF 198/458 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAA11 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- NBPF11 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 178/961 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- NELL1 | c.1314dup p.A439Cfs*3 | Frame Shift Ins (INS) | VAF 27/159 reads (17%) | called by mutect2, pindel, varscan2
- NLRP3 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP8 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- NOL4 | c.1747A>T p.R583* | Nonsense Mutation (SNP) | VAF 98/218 reads (45%) | called by muse, mutect2, varscan2
- NOVA1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 69/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NRXN3 | c.662G>A p.G221E (on ENST00000557594 / NM_001272020.2; = p.G853E on NM_004796.6) | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- NSUN2 | c.1915A>T p.R639* | Nonsense Mutation (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- NTSR2 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NUB1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NUP205 | c.2328T>A p.Y776* | Nonsense Mutation (SNP) | VAF 69/262 reads (26%) | called by muse, varscan2
- NUP205 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 69/262 reads (26%) | called by muse, varscan2
- NXPH4 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 90/617 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NYX | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2
- OBI1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11H12 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by mutect2, varscan2
- OR12D3 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- OR14C36 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR2AK2 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR2C1 | c.318G>T p.W106C | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4C15 | c.551A>T p.H184L (on ENST00000314644; = p.H130L on NM_001001920.2) | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- OR4C5 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- OR51Q1 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR5AC2 | c.86_90del p.F29Cfs*52 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- OR6N1 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B3 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- OXCT1 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OXR1 | c.970G>T p.A324S (on ENST00000442977 / NM_001198532.1; = p.A323S on NM_018002.3) | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PAK5 | c.1210dup p.L404Pfs*27 | Frame Shift Ins (INS) | VAF 172/394 reads (44%) | called by mutect2, pindel, varscan2
- PARPBP | c.669G>T p.V223= | Splice Region (SNP) | VAF 62/222 reads (28%) | called by muse, mutect2, varscan2
- PBDC1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- PCDHB12 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PCK1 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 171/514 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCK1 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX4 | c.2582G>T p.R861M (on ENST00000406854 / NM_001330177.2; = p.R627M on NM_022495.5) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, varscan2
- PCNX4 | c.2590G>T p.D864Y (on ENST00000406854 / NM_001330177.2; = p.D630Y on NM_022495.5) | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, varscan2
- PCSK5 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PEAK1 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PGR | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 163/497 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PHKA1 | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PIWIL1 | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PKD1 | c.11260C>G p.L3754V (on ENST00000262304 / NM_001009944.3; = p.L3753V on NM_000296.4) | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PKMYT1 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PLA2G4A | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 146/569 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCH2 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, varscan2
- POLA1 | c.4242del p.D1415Ifs*3 | Frame Shift Del (DEL) | VAF 34/226 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.1382G>C p.G461A | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRR14L | c.3560G>T p.G1187V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRR5L | c.444+1G>T p.X148_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2729C>G p.P910R | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PWWP3B | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PXDNL | c.2679C>A p.Y893* | Nonsense Mutation (SNP) | VAF 59/290 reads (20%) | called by muse, mutect2, varscan2
- PZP | c.2552C>G p.S851C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- R3HDM2 | c.1546-1G>T p.X516_splice | Splice Site (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- RAB5IF | c.20A>T p.K7M | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- RAC3 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 174/414 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RAD51AP2 | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- RAI14 | c.2570A>T p.Q857L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2
- RAPGEF6 | c.4331A>T p.E1444V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBPJL | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RDH16 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- REPIN1 | c.1397A>T p.K466M | Missense Mutation (SNP) | VAF 206/561 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RIPK1 | c.70_71insT p.D24Vfs*32 | Frame Shift Ins (INS) | VAF 46/384 reads (12%) | called by mutect2, pindel, varscan2
- RMND1 | c.186_212del p.L62_N71delinsF | In Frame Del (DEL) | VAF 36/276 reads (13%) | called by mutect2, pindel
- RTL1 | c.3920A>T p.H1307L | Missense Mutation (SNP) | VAF 102/593 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTP5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RYR3 | c.12293C>A p.A4098E (on ENST00000389232; = p.A4099E on NM_001036.6) | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S100A6 | c.111_125del p.I38_L42del | In Frame Del (DEL) | VAF 68/338 reads (20%) | called by mutect2, varscan2
- SALL1 | c.2608A>T p.M870L | Missense Mutation (SNP) | VAF 124/221 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SALL3 | c.1611_1612del p.H538Rfs*57 | Frame Shift Del (DEL) | VAF 126/347 reads (36%) | called by pindel, varscan2
- SAMD9L | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2
- SAPCD2 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 83/153 reads (54%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SCRN2 | c.761G>C p.R254P | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SEC14L1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- SELP | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.187); called by muse, varscan2
- SERPINB11 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 139/208 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SFTPD | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- SH3PXD2B | c.2143A>T p.K715* | Nonsense Mutation (SNP) | VAF 75/192 reads (39%) | called by muse, mutect2, varscan2
- SHROOM2 | c.2422G>C p.V808L | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC1 | c.3922T>A p.S1308T | Missense Mutation (SNP) | VAF 548/1048 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SLC22A8 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A6 | c.1384A>T p.T462S | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- SLC43A3 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SLC4A4 | c.868G>T p.G290W (on ENST00000264485 / NM_001098484.3; = p.G246W on NM_003759.4) | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A3 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 108/357 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SLFN12L | c.1587A>T p.Q529H (on ENST00000260908 / NM_001363830.1; = p.Q547H on NM_001195790.1) | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK5 | c.1350C>A p.D450E | Missense Mutation (SNP) | VAF 186/466 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SNTG2 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX18 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP140 | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SPAG6 | c.1499G>T p.R500M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- SPATA31D1 | c.4595G>C p.R1532P | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SPTA1 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 60/417 reads (14%) | called by muse, mutect2, varscan2
- STAG2 | c.1320A>T p.R440S | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STX1B | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SYT8 | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TANC1 | c.4051-1G>C p.X1351_splice | Splice Site (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- TAS2R60 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TBC1D25 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D5 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 132/388 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TCF20 | c.4755G>T p.E1585D | Missense Mutation (SNP) | VAF 95/541 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TMEM102 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 103/522 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM104 | c.731-2A>T p.X244_splice | Splice Site (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- TMPRSS11D | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMPRSS5 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPO | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRDN | c.2057T>A p.I686N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- TRDV1 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRHR | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TRIM77 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- TRIOBP | c.2753G>T p.G918V | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TRPC7 | c.719T>A p.L240H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TSHZ2 | c.3042C>A p.S1014R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.88982C>A p.T29661K (on ENST00000591111; = p.T22237K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/241 reads (7%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.50691T>A p.F16897L (on ENST00000591111; = p.F9473L on NM_003319.4) | Missense Mutation (SNP) | VAF 67/161 reads (42%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.37525G>T p.D12509Y (on ENST00000591111; = p.D5085Y on NM_003319.4) | Missense Mutation (SNP) | VAF 72/198 reads (36%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.17943A>G p.I5981M (on ENST00000591111; = p.I5054M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | PolyPhen possibly damaging (0.731); called by mutect2, varscan2
- TUBB8 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 216/846 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBGCP3 | c.1927C>G p.H643D | Missense Mutation (SNP) | VAF 39/561 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- UNC13A | c.3905G>T p.R1302L | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UPP1 | c.380A>C p.Y127S | Missense Mutation (SNP) | VAF 148/493 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- USP11 | c.393C>G p.I131M (on ENST00000218348; = p.I88M on NM_001371072.1) | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- USP11 | c.2399G>T p.W800L (on ENST00000218348; = p.W757L on NM_001371072.1) | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP11 | c.2399+1G>T p.X800_splice (on ENST00000218348; = p.X757_splice on NM_001371072.1) | Splice Site (SNP) | VAF 46/213 reads (22%) | called by muse, mutect2, varscan2
- VPS8 | c.2464G>T p.E822* (on ENST00000625842 / NM_001349294.1; = p.E820* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/123 reads (43%) | called by muse, mutect2, varscan2
- WDHD1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- XPR1 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- ZC3H12B | c.1511A>T p.K504M | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZFHX4 | c.10517A>T p.Q3506L | Missense Mutation (SNP) | VAF 342/536 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, varscan2
- ZFPM2 | n.166G>T | Splice Region (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- ZNF106 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ZNF18 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF221 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF441 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZNF471 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- ZNF579 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF616 | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF644 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF667 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF705G | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 46/643 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- ZNF711 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF735 | c.567dup p.Y190Ifs*20 | Frame Shift Ins (INS) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- ZNF804B | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF804B | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZSCAN18 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAL | c.294C>T p.G98= | Silent (SNP) | VAF 30/228 reads (13%) | catalogued as rs765890584, COSV67500037; called by muse, mutect2, varscan2
- ADAMTS20 | c.2229A>T p.G743= | Silent (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- ADCY8 | c.288G>A p.P96= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs1218629646, COSV99651073; called by muse, mutect2, varscan2
- ADGRA2 | c.3177C>T p.S1059= | Silent (SNP) | VAF 71/688 reads (10%) | catalogued as COSV99604985; called by muse, mutect2, varscan2
- AGRN | c.2634G>C p.G878= | Silent (SNP) | VAF 22/486 reads (5%) | called by muse, mutect2
- AHR | c.1353C>A p.L451= | Silent (SNP) | VAF 138/328 reads (42%) | catalogued as COSV99619260; called by muse, mutect2, varscan2
- ALMS1 | c.4830A>T p.I1610= | Silent (SNP) | VAF 23/323 reads (7%) | called by muse, mutect2
- ANO1 | c.1764A>T p.R588= | Silent (SNP) | VAF 53/391 reads (14%) | called by muse, mutect2, varscan2
- APOB | c.7029G>A p.E2343= | Silent (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- ASCC2 | c.1236A>T p.T412= | Silent (SNP) | VAF 48/329 reads (15%) | called by muse, mutect2, varscan2
- ATRNL1 | c.114C>T p.D38= | Silent (SNP) | VAF 36/214 reads (17%) | catalogued as COSV100744510; called by muse, mutect2, varscan2
- BCL11A | c.258C>T p.S86= | Silent (SNP) | VAF 100/452 reads (22%) | catalogued as COSV59624162, COSV59629520; called by muse, mutect2, varscan2
- BMP2K | c.1212C>T p.F404= | Silent (SNP) | VAF 41/215 reads (19%) | catalogued as rs749741547; called by muse, mutect2, varscan2
- CACNA1C | c.3348G>T p.G1116= | Silent (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- CATSPER3 | c.528C>A p.T176= | Silent (SNP) | VAF 169/461 reads (37%) | catalogued as COSV99254091; called by muse, mutect2, varscan2
- CCDC168 | c.16203G>A p.L5401= | Silent (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- CCDC85C | c.330C>T p.R110= | Silent (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- CDH10 | c.759C>T p.T253= | Silent (SNP) | VAF 47/270 reads (17%) | called by muse, mutect2, varscan2
- CHCHD3 | c.42G>A p.A14= | Silent (SNP) | VAF 154/423 reads (36%) | catalogued as rs1368982139; called by muse, mutect2, varscan2
- CHML | c.1827A>T p.P609= | Silent (SNP) | VAF 103/322 reads (32%) | called by muse, mutect2, varscan2
- CLSTN3 | c.399G>A p.V133= | Silent (SNP) | VAF 44/258 reads (17%) | catalogued as rs147467911; called by muse, mutect2, varscan2
- COL11A1 | c.2133T>A p.P711= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- COL11A2 | c.3453C>T p.P1151= (on ENST00000341947 / NM_080680.3; = p.P1044= on NM_080679.2) | Silent (SNP) | VAF 79/549 reads (14%) | catalogued as COSV59501302; called by muse, mutect2, varscan2
- CPEB3 | c.303G>T p.A101= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs775973574; called by muse, mutect2, varscan2
- CSDE1 | c.2094C>T p.L698= (on ENST00000358528 / NM_001007553.3; = p.L667= on NM_007158.6) | Silent (SNP) | VAF 76/204 reads (37%) | called by muse, mutect2, varscan2
- CTNNA2 | c.318C>T p.A106= | Silent (SNP) | VAF 54/277 reads (19%) | called by muse, varscan2
- CXorf65 | c.84C>A p.I28= | Silent (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- DACH2 | c.183C>A p.G61= | Silent (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- DENND5B | c.1668A>T p.P556= | Silent (SNP) | VAF 62/254 reads (24%) | called by muse, mutect2, varscan2
- DGKI | c.384G>C p.R128= | Silent (SNP) | VAF 36/488 reads (7%) | called by muse, mutect2
- DNAH5 | c.13815A>C p.T4605= | Silent (SNP) | VAF 80/412 reads (19%) | catalogued as rs371639785; called by muse, mutect2, varscan2
- DNAH9 | c.1671G>T p.P557= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs761563082, COSV52336956; called by muse, mutect2, varscan2
- DOCK10 | c.87C>T p.A29= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as rs1457209750; called by muse, mutect2, varscan2
- DSCAML1 | c.687C>T p.I229= (on ENST00000321322; = p.I169= on NM_020693.4) | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV58391994; called by muse, mutect2, varscan2
- ELAPOR2 | c.717C>T p.D239= (on ENST00000450689 / NM_001142749.3; = p.D72= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/237 reads (16%) | called by muse, mutect2, varscan2
- ENTHD1 | c.222C>A p.S74= | Silent (SNP) | VAF 30/221 reads (14%) | catalogued as COSV57322502; called by muse, mutect2, varscan2
- EPHA7 | c.1371G>T p.R457= | Silent (SNP) | VAF 61/317 reads (19%) | called by muse, mutect2, varscan2
- EYS | c.2181G>T p.G727= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as rs1463543075, COSV65468787; called by muse, mutect2, varscan2
- FAH | c.243G>T p.A81= | Silent (SNP) | VAF 226/672 reads (34%) | called by muse, mutect2, varscan2
- FAM120B | c.1101G>T p.V367= | Silent (SNP) | VAF 59/360 reads (16%) | catalogued as rs1562521415, COSV99380148; called by muse, mutect2, varscan2
- FAM178B | c.1320G>T p.G440= | Silent (SNP) | VAF 61/504 reads (12%) | called by muse, mutect2, varscan2
- FCGBP | c.2112G>T p.L704= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- FHL1 | c.873A>G p.A291= | Silent (SNP) | VAF 55/425 reads (13%) | called by muse, mutect2, varscan2
- FREM2 | c.6789C>T p.P2263= | Silent (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- GPR32 | c.348C>A p.L116= | Silent (SNP) | VAF 278/884 reads (31%) | called by muse, mutect2, varscan2
- GPRIN3 | c.378G>A p.L126= | Silent (SNP) | VAF 33/231 reads (14%) | called by muse, mutect2, varscan2
- GRM5 | c.2475C>A p.I825= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- HAUS6 | c.1917T>C p.F639= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- HNRNPD | c.66G>C p.S22= | Silent (SNP) | VAF 109/552 reads (20%) | called by muse, mutect2, varscan2
- HUWE1 | c.3294G>A p.A1098= | Silent (SNP) | VAF 63/435 reads (14%) | catalogued as rs782368092, COSV53336969; called by muse, mutect2, varscan2
- IKBKG | c.111C>T p.I37= | Silent (SNP) | VAF 12/345 reads (3%) | catalogued as rs201460468, COSV100852989, COSV63669312; called by muse, mutect2
- INPP4B | c.2685C>T p.C895= | Silent (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- IZUMO3 | c.606G>T p.R202= (on ENST00000543880 / NM_001365008.2; = p.R196= on NM_001271706.1) | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs771327617; called by muse, mutect2, varscan2
- JPH1 | c.1698C>T p.D566= | Silent (SNP) | VAF 51/572 reads (9%) | catalogued as rs749023547, COSV100646836; called by muse, mutect2
- LAIR1 | c.15C>T p.P5= | Silent (SNP) | VAF 74/278 reads (27%) | called by muse, mutect2, varscan2
- LAMA4 | c.3795A>T p.T1265= (on ENST00000230538 / NM_001105206.3; = p.T1258= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV57893698; called by muse, mutect2
- LAMA5 | c.10452C>T p.T3484= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs754964397; called by muse, mutect2, varscan2
- LAMA5 | c.69G>A p.L23= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as rs1305805246; called by muse, mutect2, varscan2
- LAS1L | c.2178G>T p.G726= | Silent (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- LCE2A | c.147G>A p.G49= | Silent (SNP) | VAF 225/869 reads (26%) | called by muse, mutect2, varscan2
- LDHD | c.483C>T p.D161= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs377732494; called by muse, mutect2, varscan2
- LEPR | c.1680G>A p.K560= | Silent (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1035G>A p.P345= | Silent (SNP) | VAF 89/308 reads (29%) | catalogued as rs898734695, COSV54445577, COSV99701757; called by muse, mutect2, varscan2
- MADCAM1 | c.618C>A p.A206= | Silent (SNP) | VAF 62/158 reads (39%) | called by muse, mutect2, varscan2
- MAP7D1 | c.705G>T p.G235= | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- MGAM2 | c.6111T>A p.T2037= | Silent (SNP) | VAF 47/229 reads (21%) | called by muse, mutect2, varscan2
- MXRA5 | c.78C>A p.A26= | Silent (SNP) | VAF 103/517 reads (20%) | called by muse, mutect2, varscan2
- MYH14 | c.1215A>T p.G405= | Silent (SNP) | VAF 82/312 reads (26%) | called by muse, mutect2, varscan2
- MYH8 | c.4140G>A p.T1380= | Silent (SNP) | VAF 129/651 reads (20%) | catalogued as rs769844559; called by muse, mutect2, varscan2
- NCLN | c.72C>G p.V24= | Silent (SNP) | VAF 98/521 reads (19%) | called by muse, mutect2, varscan2
- NEUROG1 | c.366C>T p.F122= | Silent (SNP) | VAF 138/631 reads (22%) | called by muse, mutect2, varscan2
- NHSL1 | c.1638A>T p.S546= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- NKX3-2 | c.243G>T p.A81= | Silent (SNP) | VAF 167/581 reads (29%) | called by muse, mutect2, varscan2
- NOTCH4 | c.4036C>A p.R1346= | Silent (SNP) | VAF 183/444 reads (41%) | catalogued as COSV66680932, COSV66682188; called by muse, mutect2, varscan2
- NRROS | c.747C>A p.A249= | Silent (SNP) | VAF 16/500 reads (3%) | catalogued as COSV60744828; called by muse, mutect2
- OBI1 | c.1329A>T p.S443= | Silent (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- OPRL1 | c.1044C>T p.R348= | Silent (SNP) | VAF 48/458 reads (10%) | catalogued as rs758599272, COSV61091485; called by muse, mutect2, varscan2
- OR1C1 | c.273T>C p.T91= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- OR2A25 | c.361C>A p.R121= | Silent (SNP) | VAF 90/769 reads (12%) | catalogued as COSV68717390; called by muse, mutect2, varscan2
- OR9A4 | c.678C>G p.L226= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- OTOGL | c.5013C>T p.F1671= (on ENST00000547103; = p.F1662= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/932 reads (7%) | catalogued as rs370770667; called by muse, mutect2
- PCDH8 | c.1725C>G p.L575= | Silent (SNP) | VAF 98/230 reads (43%) | called by muse, mutect2, varscan2
- PDCD1 | c.759T>C p.F253= | Silent (SNP) | VAF 72/286 reads (25%) | catalogued as rs933937651; called by muse, mutect2, varscan2
- PDZRN4 | c.2725C>A p.R909= (on ENST00000402685 / NM_001164595.2; = p.R651= on NM_013377.4) | Silent (SNP) | VAF 81/319 reads (25%) | called by muse, mutect2, varscan2
- PHKA1 | c.1308C>A p.P436= | Silent (SNP) | VAF 44/486 reads (9%) | called by muse, mutect2
- PIGN | c.2301C>T p.F767= | Silent (SNP) | VAF 73/216 reads (34%) | called by muse, mutect2, varscan2
- PLCB4 | c.2526C>T p.L842= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- PNRC1 | c.15C>T p.S5= | Silent (SNP) | VAF 163/874 reads (19%) | catalogued as rs376425738; called by muse, mutect2, varscan2
- PPFIA4 | c.2868G>T p.L956= (on ENST00000447715; = p.L957= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/617 reads (3%) | called by muse, mutect2
- PPP2R2C | c.18G>T p.T6= | Silent (SNP) | VAF 165/711 reads (23%) | called by muse, mutect2, varscan2
- PRDM1 | c.1426C>A p.R476= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV64844874; called by muse, mutect2, varscan2
- PXDN | c.3465G>T p.A1155= | Silent (SNP) | VAF 123/491 reads (25%) | catalogued as COSV53245502; called by muse, mutect2, varscan2
- RAB11FIP5 | c.189G>C p.T63= | Silent (SNP) | VAF 85/548 reads (16%) | catalogued as COSV50259143; called by muse, mutect2, varscan2
- RELB | c.375G>T p.P125= | Silent (SNP) | VAF 94/389 reads (24%) | catalogued as rs746034758, COSV99673057; called by muse, mutect2, varscan2
- RELN | c.813T>C p.G271= | Silent (SNP) | VAF 125/374 reads (33%) | catalogued as COSV58987392; called by muse, varscan2
- RGMA | c.804G>A p.Q268= | Silent (SNP) | VAF 120/762 reads (16%) | catalogued as rs1449068092; called by muse, mutect2, varscan2
- RHBDL3 | c.957T>C p.F319= | Silent (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- RNF113A | c.366G>A p.L122= | Silent (SNP) | VAF 40/375 reads (11%) | called by muse, mutect2, varscan2
- RTL10 | c.267C>T p.S89= | Silent (SNP) | VAF 71/399 reads (18%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.663C>A p.A221= (on ENST00000265814 / NM_001198628.1; = p.A194= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 559/767 reads (73%) | called by muse, mutect2, varscan2
- SAMD9L | c.2775G>T p.L925= | Silent (SNP) | VAF 14/137 reads (10%) | called by mutect2, varscan2
- SCN5A | c.723G>A p.G241= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs776453610, COSV100346446; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA6A | c.2658C>A p.A886= | Silent (SNP) | VAF 154/359 reads (43%) | called by muse, mutect2, varscan2
- SHROOM2 | c.3261G>T p.V1087= | Silent (SNP) | VAF 71/343 reads (21%) | called by muse, mutect2
- SIGLECL1 | c.366G>A p.A122= | Silent (SNP) | VAF 112/443 reads (25%) | catalogued as rs74462590; called by muse, mutect2, varscan2
- SLC19A1 | c.1746A>C p.P582= | Silent (SNP) | VAF 20/656 reads (3%) | called by muse, mutect2
- SLC22A12 | c.969C>T p.A323= | Silent (SNP) | VAF 196/753 reads (26%) | called by muse, mutect2, varscan2
- SLC2A4 | c.1473G>A p.E491= | Silent (SNP) | VAF 215/493 reads (44%) | called by muse, mutect2, varscan2
- SLC9B1 | c.294G>A p.L98= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs767941704, COSV56470743; called by muse, mutect2, varscan2
- SOWAHD | c.366C>A p.A122= | Silent (SNP) | VAF 40/314 reads (13%) | called by muse, mutect2, varscan2
- SOX4 | c.642G>T p.P214= | Silent (SNP) | VAF 23/44 reads (52%) | called by muse, varscan2
- SPTBN4 | c.990C>T p.G330= | Silent (SNP) | VAF 135/488 reads (28%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.708G>T p.V236= | Silent (SNP) | VAF 70/282 reads (25%) | called by muse, mutect2, varscan2
- SYT3 | c.498G>A p.S166= | Silent (SNP) | VAF 76/342 reads (22%) | called by muse, mutect2, varscan2
- TAS2R39 | c.183T>A p.A61= | Silent (SNP) | VAF 8/187 reads (4%) | called by muse, mutect2
- TDRD9 | c.1137C>T p.A379= | Silent (SNP) | VAF 35/286 reads (12%) | catalogued as rs779152292; called by muse, mutect2, varscan2
- TMEM235 | c.345G>T p.L115= | Silent (SNP) | VAF 82/660 reads (12%) | called by muse, mutect2
- TRAK1 | c.2127G>T p.V709= | Silent (SNP) | VAF 37/269 reads (14%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1299C>T p.T433= | Silent (SNP) | VAF 77/305 reads (25%) | called by muse, mutect2, varscan2
- TRIML2 | c.406C>T p.L136= | Silent (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- TTC28 | c.7305C>A p.R2435= | Silent (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- TTLL3 | c.2139C>T p.F713= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as rs772904208; called by muse, mutect2
- VCAM1 | c.1650C>A p.L550= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as COSV54119541; called by muse, mutect2, varscan2
- XDH | c.3300A>G p.K1100= | Silent (SNP) | VAF 70/945 reads (7%) | called by muse, mutect2
- ZFHX4 | c.10626T>A p.P3542= | Silent (SNP) | VAF 258/452 reads (57%) | catalogued as rs1338716606; called by muse, varscan2
- ZNF208 | c.2526T>C p.F842= | Silent (SNP) | VAF 79/212 reads (37%) | catalogued as rs1209465433; called by muse, mutect2, varscan2
- ZNF385C | c.24C>A p.P8= | Silent (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- ZNF503 | c.951C>A p.S317= | Silent (SNP) | VAF 169/750 reads (23%) | called by muse, mutect2, varscan2
- ZNF579 | c.108C>T p.G36= | Silent (SNP) | VAF 137/362 reads (38%) | called by muse, mutect2, varscan2
- ZNF618 | c.585G>A p.K195= (on ENST00000374126 / NM_001318042.2; = p.K163= on NM_133374.2) | Silent (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- AC011525.1 | n.701G>T | RNA (SNP) | VAF 50/146 reads (34%) | called by muse, varscan2
- AC097462.3 | n.51+334C>A | Intron (SNP) | VAF 49/179 reads (27%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+5498C>A | Intron (SNP) | VAF 115/238 reads (48%) | called by muse, mutect2, varscan2
- AC112695.1 | n.279G>T | RNA (SNP) | VAF 22/74 reads (30%) | catalogued as rs1347544332; called by muse, mutect2, varscan2
- AC235097.1 | n.119A>T | RNA (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840464 G>A | 5'Flank (SNP) | VAF 172/1607 reads (11%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822487 C>T | 5'Flank (SNP) | VAF 49/226 reads (22%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826066 C>A | 5'Flank (SNP) | VAF 74/243 reads (30%) | catalogued as rs1229863873; called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-32G>T | Intron (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- BCL9L | c.*13G>T | 3'UTR (SNP) | VAF 24/120 reads (20%) | called by muse, varscan2
- BPHL | c.664+549T>A | Intron (SNP) | VAF 28/222 reads (13%) | catalogued as COSV66743524; called by mutect2, varscan2
- BPIFA3 | c.622-10G>C | Intron (SNP) | VAF 104/457 reads (23%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-377G>T | Intron (SNP) | VAF 150/400 reads (38%) | called by muse, mutect2, varscan2
- C22orf34 | n.211A>T | RNA (SNP) | VAF 70/246 reads (28%) | called by muse, mutect2, varscan2
- CCDC22 | c.-38G>T | 5'UTR (SNP) | VAF 121/658 reads (18%) | called by muse, mutect2, varscan2
- CDH9 | c.999+33G>T | Intron (SNP) | VAF 80/342 reads (23%) | called by muse, mutect2, varscan2
- CFAP20DC | c.2237+12081C>T | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- CHRND | c.*1171G>T | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- CLCN1 | c.-23G>A | 5'UTR (SNP) | VAF 118/332 reads (36%) | called by muse, mutect2, varscan2
- CYS1 | chr2:10083787 C>A | 5'Flank (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- DCHS2 | n.7321G>T | RNA (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.*42G>A | 3'UTR (SNP) | VAF 19/122 reads (16%) | catalogued as rs769917956; called by muse, mutect2, varscan2
- DDX39A | c.-5+307C>T | Intron (SNP) | VAF 55/344 reads (16%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7106A>G | Intron (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- EYS | c.1767-6600A>T | Intron (SNP) | VAF 90/698 reads (13%) | called by muse, varscan2
- FEZ1 | c.-46+728G>C | Intron (SNP) | VAF 94/501 reads (19%) | catalogued as COSV54027974; called by muse, mutect2, varscan2
- FGF13 | c.50-127392T>A | Intron (SNP) | VAF 14/151 reads (9%) | catalogued as rs1331821093; called by muse, mutect2, varscan2
- FGF14 | c.408+25G>A | Intron (SNP) | VAF 230/610 reads (38%) | called by muse, mutect2, varscan2
- FRMPD2B | n.927G>A | RNA (SNP) | VAF 66/823 reads (8%) | catalogued as rs1241533490; called by muse, mutect2
- FTO | c.1364+50833G>C | Intron (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2
- FXYD7 | c.*34C>A | 3'UTR (SNP) | VAF 167/621 reads (27%) | catalogued as COSV99544817; called by muse, mutect2, varscan2
- GFOD1 | c.253+16116dup | Intron (INS) | VAF 94/255 reads (37%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.*59G>C | 3'UTR (SNP) | VAF 230/614 reads (37%) | called by muse, mutect2, varscan2
- GRHPR | c.494-18G>A | Intron (SNP) | VAF 134/701 reads (19%) | called by muse, mutect2, varscan2
- GRIA4 | c.1269+1378A>T | Intron (SNP) | VAF 18/84 reads (21%) | called by muse, varscan2
- H3P12 | chr3:109410142 G>A | 5'Flank (SNP) | VAF 224/492 reads (46%) | called by muse, mutect2, varscan2
- HBD | c.-29+324G>A | Intron (SNP) | VAF 67/247 reads (27%) | catalogued as rs773316939; called by muse, mutect2, varscan2
- IKBKB | c.692+485T>G | Intron (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- KEL | c.1204-22C>T | Intron (SNP) | VAF 61/442 reads (14%) | called by muse, varscan2
- KEL | c.1204-23T>A | Intron (SNP) | VAF 62/443 reads (14%) | called by muse, varscan2
- KEL | c.1204-24C>A | Intron (SNP) | VAF 63/440 reads (14%) | called by muse, varscan2
- KIDINS220 | chr2:8726888 del TTA | 3'Flank (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- KLRD1 | c.*525G>T | 3'UTR (SNP) | VAF 12/146 reads (8%) | catalogued as rs560268573; called by muse, mutect2
- LASP1 | c.*38G>T | 3'UTR (SNP) | VAF 94/332 reads (28%) | catalogued as rs1029814127; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.-493+11367G>T | Intron (SNP) | VAF 69/338 reads (20%) | called by muse, varscan2
- LINC02210-CRHR1 | c.-493+11493G>T | Intron (SNP) | VAF 62/346 reads (18%) | called by muse, varscan2
- LINC02210-CRHR1 | c.-493+11494G>T | Intron (SNP) | VAF 64/350 reads (18%) | called by muse, varscan2
- LINC02873 | n.348G>T | RNA (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+5524G>A | Intron (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- MARCHF1 | c.-322-85538A>T | Intron (SNP) | VAF 87/352 reads (25%) | catalogued as COSV72283962; called by muse, varscan2
- MEIS3 | c.13-301C>G | Intron (SNP) | VAF 42/384 reads (11%) | called by muse, mutect2, varscan2
- MICAL3 | c.2802-2329G>A | Intron (SNP) | VAF 46/299 reads (15%) | called by muse, mutect2, varscan2
- MIEN1 | c.89+41G>T | Intron (SNP) | VAF 75/491 reads (15%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92821C>A | Intron (SNP) | VAF 52/176 reads (30%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-4633G>C | Intron (SNP) | VAF 189/570 reads (33%) | catalogued as COSV100505163; called by muse, mutect2, varscan2
- MRPL20 | chr1:1400626 C>G | 3'Flank (SNP) | VAF 60/401 reads (15%) | called by muse, mutect2, varscan2
- MRRFP1 | n.100C>A | RNA (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- MYH16 | n.4093G>C | RNA (SNP) | VAF 118/501 reads (24%) | called by muse, mutect2, varscan2
- NDRG4 | c.-14C>G | 5'UTR (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- NPL | c.230+236del | Intron (DEL) | VAF 60/336 reads (18%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.3213G>T | RNA (SNP) | VAF 62/328 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-14132G>T | Intron (SNP) | VAF 89/401 reads (22%) | called by muse, mutect2, varscan2
- PPARA | c.-17A>T | 5'UTR (SNP) | VAF 69/475 reads (15%) | called by muse, mutect2, varscan2
- PPP4R1L | n.249G>T | RNA (SNP) | VAF 30/507 reads (6%) | called by muse, mutect2
- RBAK | c.16-27C>T | Intron (SNP) | VAF 68/290 reads (23%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75786546 G>T | 3'Flank (SNP) | VAF 105/634 reads (17%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792013 C>A | 3'Flank (SNP) | VAF 103/304 reads (34%) | catalogued as rs1196639990; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159731 C>A | 5'Flank (SNP) | VAF 91/441 reads (21%) | called by muse, mutect2, varscan2
- RNU4-48P | chr2:127470403 C>A | 5'Flank (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- RPL28 | c.325-63T>C | Intron (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- SERPINA13P | n.917T>A | RNA (SNP) | VAF 111/550 reads (20%) | called by muse, mutect2, varscan2
- SH2D6 | n.515G>C | RNA (SNP) | VAF 66/354 reads (19%) | called by muse, mutect2, varscan2
- SLC12A1 | c.-339C>A | 5'UTR (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- SLC13A4 | chr7:135728914 G>A | 5'Flank (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1211-37G>C | Intron (SNP) | VAF 132/794 reads (17%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.59C>T | RNA (SNP) | VAF 151/686 reads (22%) | catalogued as rs778333163; called by muse, mutect2, varscan2
- SNORD115-30 | n.58G>A | RNA (SNP) | VAF 82/373 reads (22%) | catalogued as rs768241149; called by muse, mutect2, varscan2
- SNORD116-7 | n.83A>G | RNA (SNP) | VAF 75/413 reads (18%) | catalogued as rs761553783; called by muse, mutect2, varscan2
- SP140 | c.406+455T>A | Intron (SNP) | VAF 117/283 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.3621C>T | RNA (SNP) | VAF 83/497 reads (17%) | catalogued as rs376021040; called by muse, mutect2, varscan2
- STAU2 | chr8:73420202 G>T | 3'Flank (SNP) | VAF 44/390 reads (11%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2422A>G | 3'UTR (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- TPRXL | n.874T>A | RNA (SNP) | VAF 276/766 reads (36%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.579-424C>A | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- VAPB | c.*2918A>G | 3'UTR (SNP) | VAF 385/1135 reads (34%) | catalogued as rs917619432; called by muse, mutect2, varscan2
- YTHDF3 | c.-88C>G | 5'UTR (SNP) | VAF 56/299 reads (19%) | catalogued as rs1265352678; called by muse, mutect2, varscan2
- ZNF525 | c.142+340A>C | Intron (SNP) | VAF 172/609 reads (28%) | catalogued as rs529717940; called by muse, mutect2, varscan2
- ZNF890P | n.473C>T | RNA (SNP) | VAF 52/338 reads (15%) | called by muse, mutect2, varscan2
